Somatic mutation profile of tumor specimen TCGA-A2-A04U-01A (aliquot TCGA-A2-A04U-01A-11D-A10Y-09) from TCGA case TCGA-A2-A04U, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 47.8 years (17,474 days).
Specimen TCGA-A2-A04U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34811660-5a23-4815-acb1-5dbb0d2bdd25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A04U-10A (Blood Derived Normal), aliquot TCGA-A2-A04U-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/685aada7-b285-4cd0-8f37-4cd5c27882f3

The open-access MAF lists 56 somatic variants for this specimen: 44 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 10, Frame Shift Del 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.2966G>A p.G989E | Missense Mutation (SNP) | VAF 69/229 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55950174; called by muse, mutect2, varscan2
- ADAMTS5 | c.1340A>T p.D447V | Missense Mutation (SNP) | VAF 96/466 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs765880915, COSV53178648; called by muse, mutect2, varscan2
- ALPK1 | c.3419A>T p.K1140I | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99453863; called by muse, mutect2
- BACH2 | c.1593C>G p.D531E | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV57585469, COSV57591025; called by muse, mutect2, varscan2
- BDKRB1 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 107/122 reads (88%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.595); catalogued as rs747328339, COSV53706042; called by muse, mutect2, varscan2
- CASP1 | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 106/312 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV62056425; called by muse, mutect2, varscan2
- CFAP47 | c.1499A>T p.D500V | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV52883943; called by muse, mutect2, varscan2
- CFAP65 | c.1226G>T p.C409F | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55390201, COSV99838290; called by muse, mutect2, varscan2
- CILP | c.2133A>T p.E711D | Missense Mutation (SNP) | VAF 113/133 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56023986; called by muse, mutect2, varscan2
- COLGALT1 | c.954G>C p.K318N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV99394985; called by muse, mutect2
- CPSF4 | c.296A>C p.Y99S | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52857408; called by muse, mutect2, varscan2
- CREB3 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 89/155 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59207021; called by muse, mutect2, varscan2
- EHMT1 | c.2330T>G p.L777R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58374414; called by muse, mutect2, varscan2
- ELOA2 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV55298235; called by muse, mutect2, varscan2
- ENSA | c.5C>A p.S2Y | Missense Mutation (SNP) | VAF 53/304 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); catalogued as COSV55026556; called by muse, mutect2, varscan2
- ERICH3 | c.4490T>A p.L1497H | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100444067; called by muse, mutect2
- FAN1 | c.2996del p.A999Vfs*3 | Frame Shift Del (DEL) | VAF 37/66 reads (56%) | catalogued as COSV58727997; called by mutect2, pindel, varscan2
- FMN1 | c.2578A>G p.M860V (on ENST00000616417 / NM_001277313.2; = p.M637V on NM_001103184.4) | Missense Mutation (SNP) | VAF 89/135 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57922157; called by muse, mutect2, varscan2
- FNBP4 | c.1915C>G p.Q639E | Missense Mutation (SNP) | VAF 87/439 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV55448219; called by muse, mutect2, varscan2
- FZD1 | c.1069T>A p.F357I | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs749347940, COSV55310202; called by muse, mutect2, varscan2
- GAR1 | c.31T>G p.F11V | Missense Mutation (SNP) | VAF 80/521 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.031); catalogued as COSV56993265; called by muse, mutect2, varscan2
- GNPAT | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV64153357; called by muse, mutect2, varscan2
- GPKOW | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 41/400 reads (10%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.671); catalogued as COSV99332589; called by muse, mutect2, varscan2
- GPR174 | c.492T>A p.N164K | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV52132320; called by muse, mutect2, varscan2
- KIF21B | c.1949T>G p.I650S | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59756983; called by muse, mutect2, varscan2
- LAMA3 | c.9533C>T p.P3178L (on ENST00000313654 / NM_198129.4; = p.P1569L on NM_000227.6) | Missense Mutation (SNP) | VAF 150/897 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.925); catalogued as rs756402937, COSV52534039; called by muse, mutect2, varscan2
- LMX1B | c.1078G>A p.D360N (on ENST00000373474 / NM_001174147.2; = p.D353N on NM_002316.4) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as rs772632723, COSV62739402; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEB6 | c.1180G>C p.A394P | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66872132, COSV66872187, COSV66872197; called by muse, mutect2, varscan2
- MOGAT3 | c.567C>G p.I189M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56174160; called by muse, mutect2, varscan2
- NBAS | c.6169G>T p.G2057W | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.598); catalogued as COSV55720057; called by muse, mutect2, varscan2
- NDUFV2 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100041137, COSV50821911, COSV50826323; called by muse, mutect2
- NUP35 | c.542T>G p.F181C | Missense Mutation (SNP) | VAF 50/289 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54557779; called by muse, mutect2, varscan2
- PCDHGB7 | c.1685T>G p.V562G | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53938315; called by muse, mutect2, varscan2
- POLD1 | c.3305del p.P1102Lfs*22 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | catalogued as rs761614971; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- PRDM4 | c.623G>C p.G208A | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.275); catalogued as COSV57305661; called by muse, mutect2, varscan2
- SEPTIN14 | c.36A>G p.I12M | Missense Mutation (SNP) | VAF 72/84 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.17); catalogued as COSV66427446; called by muse, mutect2, varscan2
- SLC2A13 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55116677; called by muse, mutect2, varscan2
- STRBP | c.1502G>A p.R501K | Missense Mutation (SNP) | VAF 57/282 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.074); catalogued as COSV62117913; called by muse, mutect2, varscan2
- SYT16 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 47/51 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748935569, COSV70856401; called by muse, mutect2, varscan2
- TNRC6B | c.872A>T p.D291V | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV57294766; called by muse, mutect2, varscan2
- TSPOAP1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 270/320 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757498178, COSV52107673; called by muse, mutect2, varscan2
- USP1 | c.1516T>A p.C506S | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60574305, COSV60574812; called by muse, mutect2, varscan2
- VLDLR | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs767529669, COSV66073663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.320_322delinsGC p.Y107Cfs*16 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by pindel, varscan2*
- ABCC12 | c.885A>G p.T295= | Silent (SNP) | VAF 75/231 reads (32%) | catalogued as COSV60913535; called by muse, mutect2, varscan2
- CHD2 | c.2142A>G p.E714= | Silent (SNP) | VAF 27/38 reads (71%) | catalogued as COSV67708683, COSV67709801; called by muse, mutect2, varscan2
- CNOT1 | c.6246G>A p.V2082= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as COSV55316013; called by muse, mutect2, varscan2
- MTOR | c.4365G>A p.E1455= | Silent (SNP) | VAF 52/161 reads (32%) | catalogued as COSV63870772; called by muse, mutect2, varscan2
- MXRA5 | c.126G>A p.T42= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as rs1276605250, COSV54233587; called by muse, mutect2, varscan2
- PAXIP1 | c.2526C>T p.V842= | Silent (SNP) | VAF 30/218 reads (14%) | catalogued as COSV101249580; called by muse, mutect2
- SCUBE2 | c.1404C>T p.D468= | Silent (SNP) | VAF 33/41 reads (80%) | catalogued as rs145459189; called by muse, mutect2, varscan2
- TCF7L1 | c.309C>G p.A103= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs750121496, COSV56398258; called by muse, mutect2, varscan2
- ZDHHC8 | c.489C>T p.V163= | Silent (SNP) | VAF 36/150 reads (24%) | catalogued as rs369383594; called by muse, mutect2, varscan2
- ZFYVE28 | c.762C>T p.S254= | Silent (SNP) | VAF 39/54 reads (72%) | catalogued as rs753507507, COSV52110561; called by muse, mutect2, varscan2
- HNRNPU | c.634+1173A>T | Intron (SNP) | VAF 70/364 reads (19%) | catalogued as rs538951206, COSV51690784; ClinVar: likely benign; called by muse, mutect2, varscan2
- RBM44 | c.-98-1240C>G | Intron (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100389777; called by muse, mutect2
